Somatic mutation profile of tumor specimen TCGA-29-1695-01A (aliquot TCGA-29-1695-01A-01W-0633-09) from TCGA case TCGA-29-1695, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 62.7 years (22,895 days).
Specimen TCGA-29-1695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8964d1c-4d55-486e-9afa-1466e0c09216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1695-10A (Blood Derived Normal), aliquot TCGA-29-1695-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08773c15-b77b-4cde-a59e-bb40e5026b47

The open-access MAF lists 70 somatic variants for this specimen: 51 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 17, Nonsense Mutation 5, Splice Site 2, Splice Region 2, Frame Shift Del 2, In Frame Del 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 66/106 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCF2-H2BE1 | c.1866C>T p.N622= | Splice Region (SNP) | VAF 28/160 reads (18%) | catalogued as rs142050158, COSV55182382; called by muse, mutect2, varscan2
- ADAMTS18 | c.2244C>A p.C748* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV51404852, COSV99272436; called by muse, mutect2, varscan2
- ALMS1 | c.6793C>G p.L2265V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52507894; called by muse, mutect2, varscan2
- AQP2 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV52229857; called by muse, mutect2, varscan2
- ARHGEF26 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV62845591; called by muse, mutect2, varscan2
- ATG4D | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs765209616, COSV57264280; called by muse, mutect2, varscan2
- ATP2B1 | c.3580A>G p.I1194V | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV53806582; called by muse, mutect2, varscan2
- ATP2C2 | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 65/92 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353767830, COSV52294736; called by muse, mutect2, varscan2
- ATP6V1G3 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs145635563; called by muse, mutect2
- CCL26 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV99139153; called by muse, mutect2
- CD68 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs767064051, COSV51510480; called by muse, mutect2, varscan2
- CGNL1 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs373744980; called by muse, mutect2, varscan2
- CMTR2 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as COSV57603143; called by muse, mutect2, varscan2
- CRTC3 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs563914760, COSV51595888; called by muse, mutect2, varscan2
- CSTF2T | c.674C>G p.P225R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV58656272; called by muse, mutect2, varscan2
- DDR2 | c.1857-1G>C p.X619_splice | Splice Site (SNP) | VAF 70/478 reads (15%) | catalogued as COSV63370477; called by muse, mutect2, varscan2
- DNAAF1 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.22); catalogued as rs561606647, COSV100533729, COSV57577928; called by muse, mutect2
- ELOA2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs746916831, COSV55294102; called by muse, mutect2, varscan2
- EMSY | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as COSV100595800, COSV100595856, COSV100596116; called by muse, mutect2
- ETNK1 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56884967; called by muse, mutect2, varscan2
- FASTKD3 | c.574_577del p.P192Kfs*6 | Frame Shift Del (DEL) | VAF 37/81 reads (46%) | catalogued as COSV52942845; called by mutect2, pindel, varscan2
- GRM8 | c.2356A>C p.T786P | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58819055, COSV58846868; called by muse, mutect2, varscan2
- HNRNPD | c.756T>C p.C252= | Splice Region (SNP) | VAF 44/152 reads (29%) | catalogued as COSV58313447; called by muse, mutect2, varscan2
- KCNH7 | c.3131+1G>A p.X1044_splice | Splice Site (SNP) | VAF 32/183 reads (17%) | catalogued as COSV59793891; called by muse, mutect2, varscan2
- KRT86 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as COSV53292210, COSV53292833; called by muse, mutect2, varscan2
- LMX1A | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54219546; called by muse, mutect2, varscan2
- LONRF2 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | catalogued as COSV66540302, COSV66540540; called by muse, mutect2, varscan2
- LRBA | c.6351A>C p.K2117N | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV58261513; called by muse, varscan2
- MFSD6 | c.1239G>C p.R413S | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55622179, COSV55623439; called by muse, varscan2
- MUC20 | c.1947G>T p.R649S | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV57849009; called by muse, mutect2, varscan2
- NLRP3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 109/293 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.426); catalogued as rs1299635566, COSV60222756, COSV60225404; called by muse, mutect2, varscan2
- NOBOX | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754804125, COSV56193667, COSV56194207; called by muse, mutect2, varscan2
- OR8H1 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57293753; called by muse, mutect2, varscan2
- PKD2L2 | c.57C>A p.Y19* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV51796765; called by muse, mutect2, varscan2
- POT1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62929415; called by muse, mutect2, varscan2
- PPARGC1A | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs776120045, COSV53524891, COSV53526826; called by muse, mutect2, varscan2
- PRRC2C | c.8236C>T p.R2746W (on ENST00000367742; = p.R2744W on NM_015172.4) | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs753960205, COSV58904012; called by muse, mutect2, varscan2
- RHOBTB1 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.655); catalogued as rs201889243; called by muse, mutect2, varscan2
- SH3RF3 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs760586174, COSV58684535; called by muse, mutect2, varscan2
- STK31 | c.2786A>G p.E929G | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV63455470; called by muse, mutect2, varscan2
- TFAP2D | c.1199C>G p.T400R | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1283684191, COSV50412477, COSV50466477, COSV99145834; called by muse, mutect2, varscan2
- TMEM213 | c.147del p.Q49Hfs*46 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV59474648; called by mutect2, pindel, varscan2
- TPTE | c.550C>T p.L184F (on ENST00000618007 / NM_199261.4; = p.L166F on NM_199259.4) | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as rs776946246; called by muse, mutect2, varscan2
- TRIM60 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as rs772964136, COSV61970273; called by muse, mutect2, varscan2
- TSKS | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV55874424; called by muse, mutect2, varscan2
- VEZF1 | c.535T>C p.C179R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51968055; called by muse, mutect2, varscan2
- ZMIZ1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.513); catalogued as rs758682774, COSV57893336; called by muse, mutect2, varscan2
- EHF | c.328_336del p.H110_K112del | In Frame Del (DEL) | VAF 51/196 reads (26%) | called by mutect2, pindel, varscan2
- TAF1L | c.3819_3866del p.M1273_A1288del | In Frame Del (DEL) | VAF 82/481 reads (17%) | called by mutect2, pindel
- ZNF101 | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- ADAMTS5 | c.2163C>T p.C721= | Silent (SNP) | VAF 50/342 reads (15%) | catalogued as rs201435455; called by muse, mutect2, varscan2
- ADAMTS5 | c.1374C>T p.A458= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV53178095; called by muse, mutect2, varscan2
- AL645922.1 | c.3717C>T p.H1239= | Silent (SNP) | VAF 90/833 reads (11%) | catalogued as rs537918200, COSV64887554; called by muse, mutect2, varscan2
- ALPK1 | c.915G>A p.T305= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs199945458, COSV51583396; called by muse, mutect2, varscan2
- ARHGEF26 | c.2109C>T p.V703= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV62845600; called by muse, mutect2, varscan2
- CYP11B2 | c.222G>A p.E74= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs758982680, COSV59995548; called by muse, mutect2, varscan2
- JAKMIP3 | c.474C>A p.I158= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV53822251; called by muse, mutect2, varscan2
- KLHL6 | c.234G>A p.V78= | Silent (SNP) | VAF 46/360 reads (13%) | catalogued as COSV58065782; called by muse, mutect2, varscan2
- LRFN3 | c.1545C>T p.C515= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1267485193, COSV55817441; called by muse, varscan2
- MAP1S | c.663G>A p.P221= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs142794572, COSV60722330; called by muse, mutect2, varscan2
- NPFFR2 | c.447C>A p.I149= | Silent (SNP) | VAF 47/155 reads (30%) | catalogued as COSV58148707, COSV58151688; called by muse, mutect2, varscan2
- PDGFRA | c.2760C>T p.H920= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs368291181; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXNA2 | c.2025C>T p.C675= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100885601; called by mutect2, varscan2
- SYPL2 | c.144C>T p.F48= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs368388571; called by muse, mutect2, varscan2
- SYPL2 | c.345C>T p.A115= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs371487864; called by muse, mutect2, varscan2
- TG | c.6291C>T p.A2097= | Silent (SNP) | VAF 177/1023 reads (17%) | catalogued as rs1439171639, COSV55072725; called by muse, mutect2, varscan2
- TRDMT1 | c.873G>T p.V291= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs542664811, COSV58318955; called by muse, mutect2, varscan2
- POLR3G | c.*207G>A | 3'UTR (SNP) | VAF 6/68 reads (9%) | catalogued as rs369052283; called by muse, mutect2
- RNF217-AS1 | n.3017G>T | RNA (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
